Somatic mutation profile of tumor specimen ALCH-AC0V-TTP1-A (aliquot ALCH-AC0V-TTP1-A-1-0-D-A49D-36) from ALCHEMIST case ALCH-AC0V, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 52.6 years (19,218 days).
Specimen ALCH-AC0V-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9bbbe9d4-1813-4235-8a3f-7143d80f0611.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AC0V-NB1-A (Blood Derived Normal), aliquot ALCH-AC0V-NB1-A-1-0-D-A49D-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/37dcd592-bfd1-4460-b06f-10abdd99ed9f

The open-access MAF lists 25 somatic variants for this specimen: 18 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 5, 5'UTR 1, 5'Flank 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SF3B1 | c.2098A>G p.K700E | Missense Mutation (SNP) | VAF 15/100 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs559063155, COSV59205318, COSV59216586; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CHD4 | c.3992A>G p.N1331S (on ENST00000357008 / NM_001363606.2; = p.N1344S on NM_001273.5) | Missense Mutation (SNP) | VAF 20/244 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as rs76527521; called by muse, mutect2
- EPHA5 | c.680G>C p.R227P | Missense Mutation (SNP) | VAF 102/530 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56639156; called by muse, varscan2
- KRTAP16-1 | c.868G>A p.E290K | Missense Mutation (SNP) | VAF 16/252 reads (6%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.989); catalogued as rs760350540; called by muse, mutect2
- PCDHB8 | c.403C>A p.L135M | Missense Mutation (SNP) | VAF 124/2009 reads (6%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.043); catalogued as COSV50789607, COSV99177144; called by muse, mutect2
- RGSL1 | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 26/421 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.232); catalogued as COSV54259236; called by muse, mutect2
- TAF1 | c.3293C>T p.S1098L (on ENST00000373790 / NM_138923.4; = p.S1119L on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/413 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV52121855; called by muse, mutect2
- TCEANC2 | c.363A>C p.E121D | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as rs1271041773; called by muse, mutect2, varscan2
- ZNF488 | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 22/282 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs781887190; called by muse, mutect2
- CDH9 | c.1484T>C p.F495S | Missense Mutation (SNP) | VAF 7/161 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.271); called by muse, mutect2
- EYA4 | c.839A>C p.Q280P | Missense Mutation (SNP) | VAF 12/282 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); called by muse, mutect2
- MATR3 | c.570T>A p.D190E | Missense Mutation (SNP) | VAF 38/542 reads (7%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.952); called by muse, mutect2
- OR8I2 | c.928C>A p.P310T | Missense Mutation (SNP) | VAF 5/92 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.005); called by muse, mutect2
- PLXNA2 | c.685C>A p.P229T | Missense Mutation (SNP) | VAF 44/965 reads (5%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); called by muse, mutect2
- PUM2 | c.3075C>G p.H1025Q | Missense Mutation (SNP) | VAF 21/216 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.319); called by muse, mutect2
- RYR2 | c.13522T>A p.F4508I | Missense Mutation (SNP) | VAF 15/334 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.117); called by muse, mutect2
- SPIN4 | c.541G>T p.D181Y | Missense Mutation (SNP) | VAF 96/480 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- TDRD12 | c.1753G>T p.E585* | Nonsense Mutation (SNP) | VAF 25/242 reads (10%) | called by muse, mutect2, varscan2
- CRKL | c.114C>T p.V38= | Silent (SNP) | VAF 36/580 reads (6%) | catalogued as rs745406845, COSV62884605; called by muse, mutect2
- GFY | c.312C>A p.T104= | Silent (SNP) | VAF 31/375 reads (8%) | called by muse, mutect2
- PCDHB6 | c.2028G>A p.P676= | Silent (SNP) | VAF 115/677 reads (17%) | catalogued as rs781944899, COSV50702112, COSV50709231; called by muse, mutect2, varscan2
- UBA7 | c.330C>T p.D110= | Silent (SNP) | VAF 19/187 reads (10%) | called by muse, mutect2, varscan2
- ULK2 | c.2403C>T p.S801= | Silent (SNP) | VAF 5/79 reads (6%) | catalogued as rs1379940491; called by muse, mutect2
- RNA5-8SP2 | chr16:34159380 C>T | 5'Flank (SNP) | VAF 16/152 reads (11%) | catalogued as rs562411495; called by muse, mutect2
- TBC1D12 | c.-3C>T | 5'UTR (SNP) | VAF 18/230 reads (8%) | catalogued as rs776687705, COSV56552223; called by muse, mutect2
